Somatic mutation profile of tumor specimen MMRF_2245_1_BM_CD138pos (aliquot MMRF_2245_1_BM_CD138pos_T1_KHS5U_L11037) from MMRF case MMRF_2245, project MMRF-COMMPASS (Multiple Myeloma CoMMpass Study). Sex at birth: female; Vital status: Alive; Primary diagnosis: Multiple myeloma; Tissue or organ of origin: Bone marrow; Age at diagnosis: 77.9 years (28,467 days).
Specimen MMRF_2245_1_BM_CD138pos: Sample type: Primary Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Bone Marrow NOS.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 158fc22e-119e-4628-b500-1c59d6bfe1cf.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen MMRF_2245_1_PB_WBC (Blood Derived Normal), aliquot MMRF_2245_1_PB_WBC_C2_KHS5U_L11038; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/4a913647-a8ae-4bf7-ae8f-8b5ec93e265c

The open-access MAF lists 482 somatic variants for this specimen: 173 protein-altering or splice-affecting, 45 silent, 264 other (UTR, intronic, flanking, RNA and similar).
By variant classification: 3'UTR 157, Missense Mutation 149, Intron 63, Silent 45, 5'UTR 18, 3'Flank 15, Frame Shift Del 7, 5'Flank 7, Splice Region 5, RNA 4, In Frame Del 4, Splice Site 4.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- BRAF | c.1919T>A p.V640E (on ENST00000288602 / NM_001374244.1; = p.V600E on NM_004333.6 and 3 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 13/44 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.955); catalogued as rs113488022, CM112509, COSV56056643, COSV56065204, COSV56080151; ClinVar: pathogenic / likely pathogenic / other / drug response; called by muse, mutect2, varscan2
- ABT1 | c.34G>A p.E12K | Missense Mutation (SNP) | VAF 16/162 reads (10%) | SIFT tolerated, low confidence (0.06); PolyPhen benign (0); catalogued as COSV51293290; called by muse, mutect2
- ACTN1 | c.875G>A p.R292H | Missense Mutation (SNP) | VAF 50/127 reads (39%) | SIFT deleterious (0.03); PolyPhen benign (0.161); catalogued as rs369878847; called by muse, mutect2, varscan2
- AGPS | c.1057C>T p.R353C | Missense Mutation (SNP) | VAF 6/19 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1278557979; called by muse, mutect2, varscan2
- ANGPT4 | c.1220+1G>T p.X407_splice | Splice Site (SNP) | VAF 6/17 reads (35%) | catalogued as COSV67920988; called by muse, mutect2, varscan2
- ARC | c.290G>A p.R97H | Missense Mutation (SNP) | VAF 58/132 reads (44%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.988); catalogued as rs1218485440; called by muse, mutect2, varscan2
- C15orf39 | c.2355_2356del p.P786Sfs*141 | Frame Shift Del (DEL) | VAF 34/192 reads (18%) | catalogued as rs748264257; called by pindel, varscan2
- CACTIN | c.2225A>G p.N742S | Missense Mutation (SNP) | VAF 89/342 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.988); catalogued as rs764641492; called by muse, mutect2, varscan2
- CCDC170 | c.619G>A p.V207M | Missense Mutation (SNP) | VAF 12/32 reads (38%) | SIFT tolerated (0.2); PolyPhen benign (0.007); catalogued as rs556543582; called by muse, mutect2
- CHURC1 | c.195T>A p.F65L | Missense Mutation (SNP) | VAF 57/173 reads (33%) | SIFT tolerated (0.33); PolyPhen possibly damaging (0.892); catalogued as COSV63036783; called by muse, mutect2, varscan2
- CIC | c.1985C>A p.A662D | Missense Mutation (SNP) | VAF 33/124 reads (27%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0); catalogued as COSV50650714; called by muse, mutect2, varscan2
- CLASP1 | c.1694G>A p.R565H | Missense Mutation (SNP) | VAF 25/64 reads (39%) | SIFT deleterious (0); PolyPhen possibly damaging (0.871); catalogued as rs756333219, COSV55340445; called by muse, mutect2, varscan2
- CLK3 | c.641A>G p.D214G (on ENST00000395066 / NM_001130028.1; = p.D66G on NM_003992.4) | Missense Mutation (SNP) | VAF 73/247 reads (30%) | SIFT deleterious (0.04); PolyPhen benign (0.212); catalogued as COSV100775907; called by muse, mutect2, varscan2
- COL1A1 | c.3779G>A p.R1260H | Missense Mutation (SNP) | VAF 37/100 reads (37%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.991); catalogued as rs774001209, COSV56807802; called by muse, mutect2, varscan2
- CYB561D2 | c.137_139del p.S46del | In Frame Del (DEL) | VAF 29/101 reads (29%) | catalogued as rs762536149; called by mutect2, pindel, varscan2
- DDX3X | c.676+2T>A p.X226_splice (on ENST00000399959; = p.X227_splice on NM_001356.5) | Splice Site (SNP) | VAF 37/100 reads (37%) | catalogued as COSV104433600; called by muse, mutect2, varscan2
- DLL4 | c.1030G>T p.D344Y | Missense Mutation (SNP) | VAF 40/143 reads (28%) | SIFT deleterious (0); PolyPhen benign (0.139); catalogued as COSV51074253; called by muse, mutect2, varscan2
- DSG2 | c.2654G>C p.G885A | Missense Mutation (SNP) | VAF 47/169 reads (28%) | SIFT deleterious (0.01); PolyPhen benign (0.012); catalogued as COSV55196842; called by muse, mutect2, varscan2
- DTX3L | c.1112C>T p.A371V | Missense Mutation (SNP) | VAF 68/263 reads (26%) | SIFT deleterious (0.02); PolyPhen benign (0.01); catalogued as rs1264051297; called by muse, mutect2, varscan2
- EEF1A2 | c.350C>T p.A117V | Missense Mutation (SNP) | VAF 63/137 reads (46%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.896); catalogued as rs866429985, COSV99419772; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- EXOSC3 | c.214C>T p.R72W | Missense Mutation (SNP) | VAF 44/201 reads (22%) | SIFT deleterious (0); PolyPhen possibly damaging (0.721); catalogued as rs767003713, COSV59203960; called by muse, mutect2, varscan2
- HS3ST3A1 | c.11C>T p.P4L | Missense Mutation (SNP) | VAF 16/56 reads (29%) | SIFT tolerated, low confidence (0.13); PolyPhen benign (0); catalogued as COSV52375723, COSV52380253; called by muse, mutect2, varscan2
- IFT80 | c.727T>A p.L243I | Missense Mutation (SNP) | VAF 49/166 reads (30%) | SIFT deleterious (0.02); PolyPhen benign (0.364); catalogued as COSV100424262; called by muse, mutect2, varscan2
- IGKJ4 | c.26T>C p.V9A | Missense Mutation (SNP) | VAF 17/48 reads (35%) | PolyPhen benign (0.401); catalogued as rs191518742; called by muse, varscan2
- IL1RAPL2 | c.1697G>A p.R566Q | Missense Mutation (SNP) | VAF 115/294 reads (39%) | SIFT tolerated (0.06); PolyPhen benign (0.413); catalogued as rs138952638, COSV61153176; called by muse, mutect2, varscan2
- KIAA1109 | c.7103C>G p.S2368C | Missense Mutation (SNP) | VAF 80/175 reads (46%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as COSV99148389; called by muse, mutect2, varscan2
- KIF5A | c.1228G>A p.A410T | Missense Mutation (SNP) | VAF 24/52 reads (46%) | SIFT tolerated (0.69); PolyPhen benign (0); catalogued as rs148888970; called by muse, mutect2, varscan2
- LRIG3 | c.1652A>C p.H551P | Missense Mutation (SNP) | VAF 47/110 reads (43%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.983); catalogued as rs753222629; called by muse, mutect2, varscan2
- LRRC4B | c.1255G>A p.G419S | Missense Mutation (SNP) | VAF 24/88 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1211683508; called by muse, mutect2, varscan2
- MEGF10 | c.2663C>A p.S888* | Nonsense Mutation (SNP) | VAF 44/212 reads (21%) | catalogued as COSV104387746; called by muse, mutect2, varscan2
- MYH3 | c.418G>A p.V140M | Missense Mutation (SNP) | VAF 43/98 reads (44%) | SIFT tolerated (0.09); PolyPhen probably damaging (0.915); catalogued as rs1279423718; called by muse, mutect2, varscan2
- NFATC1 | c.1271G>T p.G424V | Missense Mutation (SNP) | VAF 25/95 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.981); catalogued as COSV99500964; called by muse, mutect2, varscan2
- NIT2 | c.98C>T p.T33M | Missense Mutation (SNP) | VAF 35/120 reads (29%) | SIFT deleterious (0.03); PolyPhen benign (0.329); catalogued as rs751492664; called by muse, mutect2, varscan2
- NPEPPS | c.2645G>A p.R882H | Missense Mutation (SNP) | VAF 44/120 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs1179179896; called by muse, mutect2, varscan2
- OPTN | c.1597T>G p.Y533D | Missense Mutation (SNP) | VAF 34/84 reads (40%) | SIFT tolerated (0.13); PolyPhen benign (0.114); catalogued as rs765504038; called by muse, mutect2, varscan2
- OTUD4 | c.416T>C p.V139A (on ENST00000447906 / NM_001366057.1; = p.V74A on NM_017493.7 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 17/76 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.957); catalogued as COSV104409618; called by muse, mutect2, varscan2
- PCDH7 | c.1265G>T p.R422L | Missense Mutation (SNP) | VAF 134/333 reads (40%) | SIFT tolerated (1); PolyPhen benign (0.052); catalogued as COSV62340093; called by muse, mutect2, varscan2
- PCDHA3 | c.832G>A p.A278T | Missense Mutation (SNP) | VAF 56/241 reads (23%) | SIFT tolerated, low confidence (0.88); PolyPhen benign (0); catalogued as COSV65369243; called by muse, mutect2, varscan2
- PLXNB1 | c.4750C>T p.P1584S | Missense Mutation (SNP) | VAF 58/207 reads (28%) | SIFT tolerated (0.06); PolyPhen probably damaging (1); catalogued as rs752689854; called by muse, mutect2, varscan2
- PPP1R13L | c.2250C>T p.D750= | Splice Region (SNP) | VAF 122/412 reads (30%) | catalogued as rs1235757811, COSV62908654; called by muse, varscan2
- RNFT2 | c.674C>A p.A225E | Missense Mutation (SNP) | VAF 43/95 reads (45%) | SIFT deleterious (0.01); PolyPhen benign (0.196); catalogued as COSV99985360; called by muse, mutect2, varscan2
- SBK2 | c.652G>A p.G218R | Missense Mutation (SNP) | VAF 22/96 reads (23%) | SIFT tolerated (0.06); PolyPhen benign (0.189); catalogued as rs935026083, COSV60014089; called by muse, mutect2, varscan2
- SENP7 | c.2856T>G p.N952K | Missense Mutation (SNP) | VAF 9/46 reads (20%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.717); catalogued as rs750199913; called by muse, mutect2, varscan2
- STOX1 | c.970G>C p.E324Q | Missense Mutation (SNP) | VAF 81/319 reads (25%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.586); catalogued as rs200076324; called by muse, mutect2, varscan2
- SUGP1 | c.802G>A p.E268K | Missense Mutation (SNP) | VAF 48/161 reads (30%) | SIFT deleterious (0); PolyPhen possibly damaging (0.735); catalogued as rs369915490; called by muse, mutect2, varscan2
- TCHH | c.4319G>A p.R1440H | Missense Mutation (SNP) | VAF 82/149 reads (55%) | SIFT tolerated, low confidence (0.06); PolyPhen possibly damaging (0.467); catalogued as rs767694280; called by muse, mutect2, varscan2
- TEK | c.1237C>T p.R413W | Missense Mutation (SNP) | VAF 54/255 reads (21%) | SIFT deleterious (0); PolyPhen benign (0.42); catalogued as rs534867466, COSV101193103; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- TFR2 | c.849+3A>G | Splice Region (SNP) | VAF 69/315 reads (22%) | catalogued as rs1562841910; called by muse, mutect2, varscan2
- TMEM132B | c.1910C>T p.P637L | Missense Mutation (SNP) | VAF 9/28 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs369161319; called by muse, mutect2, varscan2
- TMEM47 | c.329G>A p.R110H | Missense Mutation (SNP) | VAF 52/144 reads (36%) | SIFT tolerated (0.16); PolyPhen possibly damaging (0.873); catalogued as rs763483683; called by muse, mutect2, varscan2
- TOR1AIP1 | c.1024C>T p.P342S | Missense Mutation (SNP) | VAF 10/41 reads (24%) | SIFT tolerated (0.5); PolyPhen benign (0.038); catalogued as rs1382333102, COSV54871067; called by muse, mutect2, varscan2
- TRAK2 | c.1097A>G p.Y366C | Missense Mutation (SNP) | VAF 36/109 reads (33%) | SIFT tolerated (0.28); PolyPhen benign (0); catalogued as rs1238512550; called by muse, mutect2, varscan2
- ZFYVE26 | c.5915C>T p.A1972V | Missense Mutation (SNP) | VAF 19/30 reads (63%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.839); catalogued as COSV61326531; called by muse, mutect2, varscan2
- ZNF423 | c.595G>A p.D199N (on ENST00000563137 / NM_001379286.1; = p.D191N on NM_015069.4) | Missense Mutation (SNP) | VAF 46/109 reads (42%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.999); catalogued as rs867011137, COSV52180778; called by muse, mutect2, varscan2
- ABCA7 | c.3740_3756del p.A1247Gfs*33 | Frame Shift Del (DEL) | VAF 20/48 reads (42%) | called by mutect2, pindel
- ADGRA2 | c.2167G>A p.G723S | Missense Mutation (SNP) | VAF 17/45 reads (38%) | SIFT tolerated (0.11); PolyPhen benign (0.053); called by muse, mutect2, varscan2
- ALDH2 | c.840G>C p.K280N | Missense Mutation (SNP) | VAF 23/80 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- ANKRD52 | c.756T>A p.D252E | Missense Mutation (SNP) | VAF 25/83 reads (30%) | SIFT tolerated (0.19); PolyPhen benign (0.029); called by muse, mutect2, varscan2
- AP2A1 | c.2472G>T p.Q824H | Missense Mutation (SNP) | VAF 25/79 reads (32%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.982); called by muse, mutect2, varscan2
- ARHGAP32 | c.3659G>C p.S1220T (on ENST00000310343 / NM_001378025.1; = p.S871T on NM_014715.4) | Missense Mutation (SNP) | VAF 79/289 reads (27%) | SIFT deleterious, low confidence (0.04); PolyPhen benign (0.023); called by muse, mutect2, varscan2
- ARID1A | c.6271T>G p.W2091G | Missense Mutation (SNP) | VAF 75/215 reads (35%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- ARNT2 | c.56C>T p.S19F | Missense Mutation (SNP) | VAF 76/272 reads (28%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0.125); called by muse, mutect2, varscan2
- ATF7IP | c.1817A>T p.K606I | Missense Mutation (SNP) | VAF 7/14 reads (50%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.956); called by muse, mutect2, varscan2
- BACE2 | c.747+2T>C p.X249_splice | Splice Site (SNP) | VAF 57/163 reads (35%) | called by muse, mutect2, varscan2
- BCAM | c.1780G>T p.G594W | Missense Mutation (SNP) | VAF 11/43 reads (26%) | SIFT deleterious (0); PolyPhen benign (0.213); called by muse, mutect2, varscan2
- BGN | c.116A>G p.E39G | Missense Mutation (SNP) | VAF 59/272 reads (22%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.96); called by muse, mutect2, varscan2
- BOD1L1 | c.4433A>C p.E1478A | Missense Mutation (SNP) | VAF 65/136 reads (48%) | SIFT deleterious (0); PolyPhen benign (0.196); called by muse, mutect2, varscan2
- BPHL | c.665-7C>T | Splice Region (SNP) | VAF 15/61 reads (25%) | called by muse, mutect2
- CAPN7 | c.851A>C p.Q284P | Missense Mutation (SNP) | VAF 22/121 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- CATSPERD | c.821A>T p.D274V | Missense Mutation (SNP) | VAF 27/122 reads (22%) | SIFT deleterious (0.03); PolyPhen benign (0.421); called by muse, mutect2, varscan2
- CC2D1A | c.505G>A p.G169R | Missense Mutation (SNP) | VAF 43/218 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- CFAP54 | c.3301A>T p.K1101* | Nonsense Mutation (SNP) | VAF 15/42 reads (36%) | called by muse, mutect2, varscan2
- CLEC2B | c.332T>G p.F111C | Missense Mutation (SNP) | VAF 24/64 reads (38%) | SIFT deleterious (0.01); PolyPhen benign (0.348); called by muse, mutect2, varscan2
- CLNK | c.906G>T p.K302N | Missense Mutation (SNP) | VAF 24/63 reads (38%) | SIFT deleterious (0); PolyPhen possibly damaging (0.738); called by muse, mutect2, varscan2
- CNOT4 | c.97T>A p.C33S | Missense Mutation (SNP) | VAF 64/279 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- CSNK1E | c.119A>T p.E40V | Missense Mutation (SNP) | VAF 24/69 reads (35%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- DMTF1 | c.1742_1752del p.T581Ifs*9 | Frame Shift Del (DEL) | VAF 57/287 reads (20%) | called by mutect2, pindel, varscan2
- DNAJB11 | c.577T>A p.C193S | Missense Mutation (SNP) | VAF 22/88 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- DYM | c.1658T>A p.L553* | Nonsense Mutation (SNP) | VAF 54/204 reads (26%) | called by muse, mutect2
- DYM | c.1656C>G p.N552K | Missense Mutation (SNP) | VAF 52/204 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); called by muse, mutect2
- EIF4ENIF1 | c.1400G>C p.S467T | Missense Mutation (SNP) | VAF 23/82 reads (28%) | SIFT tolerated (1); PolyPhen benign (0.015); called by muse, mutect2, varscan2
- ELOVL1 | c.68C>A p.P23H | Missense Mutation (SNP) | VAF 47/148 reads (32%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.992); called by muse, mutect2, varscan2
- EML6 | c.458T>C p.I153T | Missense Mutation (SNP) | VAF 18/58 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.93); called by muse, mutect2, varscan2
- ESPL1 | c.616G>A p.D206N | Missense Mutation (SNP) | VAF 107/290 reads (37%) | SIFT deleterious (0.01); PolyPhen benign (0.205); called by muse, mutect2, varscan2
- EYA1 | c.773T>C p.L258P | Missense Mutation (SNP) | VAF 37/110 reads (34%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- FAN1 | c.2155T>A p.L719M | Missense Mutation (SNP) | VAF 83/304 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); called by muse, mutect2, varscan2
- FBXO22 | c.629G>A p.G210D | Missense Mutation (SNP) | VAF 16/61 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- FCF1 | c.47T>A p.M16K | Missense Mutation (SNP) | VAF 74/241 reads (31%) | SIFT tolerated (0.08); PolyPhen benign (0.127); called by muse, mutect2, varscan2
- FEM1B | c.884T>C p.V295A | Missense Mutation (SNP) | VAF 82/261 reads (31%) | SIFT tolerated (0.38); PolyPhen benign (0.081); called by muse, mutect2, varscan2
- FLNA | c.7924T>C p.Y2642H (on ENST00000369850 / NM_001110556.2; = p.Y2634H on NM_001456.3) | Missense Mutation (SNP) | VAF 27/125 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.946); called by muse, mutect2, varscan2
- GABBR1 | c.1001G>C p.G334A | Missense Mutation (SNP) | VAF 19/87 reads (22%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.656); called by muse, mutect2
- GASK1B | c.940G>A p.D314N | Missense Mutation (SNP) | VAF 29/82 reads (35%) | SIFT deleterious (0); PolyPhen benign (0.394); called by muse, mutect2, varscan2
- GMEB2 | c.236T>C p.M79T | Missense Mutation (SNP) | VAF 65/167 reads (39%) | SIFT tolerated (0.58); PolyPhen benign (0.01); called by muse, mutect2, varscan2
- GRK6 | c.1417T>A p.Y473N | Missense Mutation (SNP) | VAF 31/102 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.937); called by muse, mutect2, varscan2
- GSK3A | c.1156T>C p.Y386H | Missense Mutation (SNP) | VAF 22/127 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- HAS3 | c.1097T>C p.L366P | Missense Mutation (SNP) | VAF 93/255 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- HCFC1 | c.3317A>C p.N1106T | Missense Mutation (SNP) | VAF 58/102 reads (57%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.043); called by muse, mutect2, varscan2
- HECTD4 | c.4825T>A p.W1609R | Missense Mutation (SNP) | VAF 84/194 reads (43%) | SIFT tolerated (0.18); PolyPhen probably damaging (0.991); called by muse, varscan2
- HERC2 | c.9687G>T p.W3229C | Missense Mutation (SNP) | VAF 96/433 reads (22%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- HIVEP1 | c.8104T>G p.F2702V | Missense Mutation (SNP) | VAF 80/262 reads (31%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.547); called by muse, mutect2, varscan2
- HOOK3 | c.92C>A p.T31N | Missense Mutation (SNP) | VAF 78/192 reads (41%) | SIFT tolerated (0.13); PolyPhen benign (0.026); called by muse, mutect2, varscan2
- HSPA5 | c.20C>A p.A7D | Missense Mutation (SNP) | VAF 64/105 reads (61%) | SIFT tolerated, low confidence (0.22); PolyPhen benign (0.137); called by muse, mutect2, varscan2
- IFIT5 | c.683T>G p.V228G | Missense Mutation (SNP) | VAF 65/178 reads (37%) | SIFT deleterious (0.01); PolyPhen benign (0.185); called by muse, mutect2, varscan2
- KIAA1109 | c.10631G>C p.R3544T | Missense Mutation (SNP) | VAF 49/126 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.977); called by muse, mutect2, varscan2
- KMT2B | c.4162T>A p.Y1388N | Missense Mutation (SNP) | VAF 87/342 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- KSR2 | c.1151C>T p.T384I | Missense Mutation (SNP) | VAF 9/23 reads (39%) | SIFT tolerated (0.08); PolyPhen benign (0.01); called by muse, mutect2, varscan2
- LHX9 | c.1010C>T p.A337V | Missense Mutation (SNP) | VAF 84/359 reads (23%) | SIFT tolerated (0.35); PolyPhen benign (0.007); called by muse, mutect2, varscan2
- LY9 | c.401A>G p.N134S | Missense Mutation (SNP) | VAF 88/361 reads (24%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.824); called by muse, mutect2, varscan2
- MAML2 | c.464_469del p.Q155_P156del | In Frame Del (DEL) | VAF 48/156 reads (31%) | called by pindel, varscan2
- MDM4 | c.382A>G p.M128V | Missense Mutation (SNP) | VAF 57/223 reads (26%) | SIFT tolerated (0.74); PolyPhen benign (0); called by muse, mutect2, varscan2
- MED15 | c.944C>T p.P315L | Missense Mutation (SNP) | VAF 52/145 reads (36%) | SIFT tolerated, low confidence (0.13); PolyPhen benign (0.023); called by muse, mutect2, varscan2
- MORF4L1 | c.248T>A p.V83E | Missense Mutation (SNP) | VAF 33/181 reads (18%) | SIFT tolerated, low confidence (0.17); PolyPhen possibly damaging (0.775); called by muse, mutect2, varscan2
- MTMR4 | c.1259T>G p.L420R | Missense Mutation (SNP) | VAF 30/103 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- MTMR8 | c.1690A>T p.S564C | Missense Mutation (SNP) | VAF 29/67 reads (43%) | SIFT deleterious (0); PolyPhen possibly damaging (0.57); called by muse, mutect2, varscan2
- NF1 | c.4144G>A p.V1382I | Missense Mutation (SNP) | VAF 33/81 reads (41%) | SIFT deleterious, low confidence (0.04); PolyPhen probably damaging (0.956); called by muse, mutect2, varscan2
- NFKBIE | c.1074_1075del p.H359Lfs*36 (on ENST00000275015; = p.H220Lfs*36 on NM_004556.3) | Frame Shift Del (DEL) | VAF 36/162 reads (22%) | called by pindel, varscan2
- NICN1 | c.320A>T p.D107V | Missense Mutation (SNP) | VAF 158/492 reads (32%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.648); called by muse, varscan2
- NOL10 | c.1306A>C p.T436P | Missense Mutation (SNP) | VAF 5/17 reads (29%) | SIFT tolerated (0.11); PolyPhen benign (0.239); called by muse, mutect2, varscan2
- NYAP1 | c.1013_1021del p.L338_F340del | In Frame Del (DEL) | VAF 80/356 reads (22%) | called by mutect2, pindel, varscan2
- OR1B1 | c.712G>T p.A238S | Missense Mutation (SNP) | VAF 87/291 reads (30%) | SIFT tolerated (0.44); PolyPhen benign (0.219); called by muse, mutect2, varscan2
- PAK4 | c.1578G>A p.M526I | Missense Mutation (SNP) | VAF 102/369 reads (28%) | SIFT deleterious (0.01); PolyPhen benign (0.414); called by muse, mutect2, varscan2
- PGLYRP1 | c.191G>A p.G64D | Missense Mutation (SNP) | VAF 23/119 reads (19%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.982); called by muse, mutect2, varscan2
- PHF14 | c.1903G>A p.E635K | Missense Mutation (SNP) | VAF 4/18 reads (22%) | SIFT tolerated (0.32); PolyPhen benign (0.321); called by muse, mutect2, varscan2
- PITRM1 | c.2497C>G p.P833A | Missense Mutation (SNP) | VAF 50/139 reads (36%) | SIFT tolerated (0.8); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- PLEKHG3 | c.2224G>C p.G742R (on ENST00000394691; = p.G798R on NM_001308147.2) | Missense Mutation (SNP) | VAF 39/106 reads (37%) | SIFT tolerated (0.2); PolyPhen benign (0.02); called by muse, mutect2, varscan2
- PNPLA6 | c.298A>G p.K100E (on ENST00000414982 / NM_001166111.2; = p.K52E on NM_006702.5) | Missense Mutation (SNP) | VAF 57/227 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); called by muse, mutect2, varscan2
- PSMC2 | c.1018A>C p.K340Q | Missense Mutation (SNP) | VAF 67/229 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- PTK7 | c.911del p.Q304Rfs*16 | Frame Shift Del (DEL) | VAF 32/172 reads (19%) | called by mutect2, pindel, varscan2
- RAPGEF2 | c.2465T>A p.L822Q | Missense Mutation (SNP) | VAF 20/72 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- REV3L | c.8504A>G p.Y2835C | Missense Mutation (SNP) | VAF 28/95 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- REV3L | c.6427G>A p.D2143N | Missense Mutation (SNP) | VAF 75/193 reads (39%) | SIFT tolerated (0.35); PolyPhen benign (0); called by muse, mutect2, varscan2
- RIN1 | c.277G>T p.V93L | Missense Mutation (SNP) | VAF 54/179 reads (30%) | SIFT deleterious (0); PolyPhen possibly damaging (0.654); called by muse, mutect2, varscan2
- RUNDC1 | c.1435T>G p.Y479D | Missense Mutation (SNP) | VAF 123/310 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- SAMHD1 | c.1272T>G p.D424E | Missense Mutation (SNP) | VAF 6/16 reads (38%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.863); called by muse, mutect2, varscan2
- SASH1 | c.74C>G p.P25R | Missense Mutation (SNP) | VAF 32/77 reads (42%) | SIFT tolerated, low confidence (0.13); PolyPhen benign (0.02); called by muse, mutect2, varscan2
- SEC22B | c.607T>C p.F203L | Missense Mutation (SNP) | VAF 12/69 reads (17%) | SIFT tolerated (0.4); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- SEC23B | c.1966T>G p.F656V | Missense Mutation (SNP) | VAF 34/103 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.955); called by muse, mutect2, varscan2
- SEC31B | c.2407G>T p.V803L | Missense Mutation (SNP) | VAF 19/50 reads (38%) | SIFT deleterious (0.04); PolyPhen benign (0.085); called by muse, mutect2, varscan2
- SENP8 | c.20G>C p.S7T | Missense Mutation (SNP) | VAF 169/672 reads (25%) | SIFT deleterious (0.01); PolyPhen benign (0.245); called by muse, mutect2, varscan2
- SGSM2 | c.1682A>T p.Q561L (on ENST00000426855 / NM_001098509.2; = p.Q606L on NM_014853.3) | Missense Mutation (SNP) | VAF 87/231 reads (38%) | SIFT tolerated (1); PolyPhen benign (0); called by muse, mutect2, varscan2
- SHH | c.1118C>A p.A373E | Missense Mutation (SNP) | VAF 24/61 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- SMIM26 | c.120A>C p.V40= | Splice Region (SNP) | VAF 19/45 reads (42%) | called by muse, mutect2, varscan2
- SPATA5L1 | c.1434+2T>A p.X478_splice | Splice Site (SNP) | VAF 43/165 reads (26%) | called by muse, mutect2, varscan2
- SUSD4 | c.575A>G p.N192S | Missense Mutation (SNP) | VAF 20/95 reads (21%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.932); called by muse, mutect2, varscan2
- SYNE1 | c.13587G>C p.K4529N (on ENST00000367255 / NM_182961.4; = p.K4458N on NM_033071.3) | Missense Mutation (SNP) | VAF 106/277 reads (38%) | SIFT tolerated (0.07); PolyPhen benign (0.444); called by muse, mutect2, varscan2
- TBC1D21 | c.187A>T p.R63W | Missense Mutation (SNP) | VAF 63/246 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- TCF12 | c.1913A>T p.N638I | Missense Mutation (SNP) | VAF 53/216 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); called by muse, mutect2, varscan2
- TCHHL1 | c.562C>A p.Q188K | Missense Mutation (SNP) | VAF 70/308 reads (23%) | SIFT deleterious (0.03); PolyPhen benign (0.038); called by muse, mutect2, varscan2
- TMEM106C | c.26_28del p.A9_R10delinsG | In Frame Del (DEL) | VAF 68/231 reads (29%) | called by mutect2, pindel, varscan2
- TMEM87B | c.904G>T p.V302L | Missense Mutation (SNP) | VAF 14/106 reads (13%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.883); called by muse, mutect2
- TNFAIP3 | c.743T>C p.I248T | Missense Mutation (SNP) | VAF 49/131 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.937); called by muse, mutect2, varscan2
- TOP2B | c.1266A>T p.A422= (on ENST00000264331 / NM_001330700.2; = p.A417= on NM_001068.3) | Splice Region (SNP) | VAF 5/15 reads (33%) | called by muse, mutect2
- TRAF3IP3 | c.508del p.A170Qfs*42 | Frame Shift Del (DEL) | VAF 76/340 reads (22%) | called by mutect2, pindel, varscan2
- TRBC1 | c.365G>T p.S122I | Missense Mutation (SNP) | VAF 16/77 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); called by muse, mutect2, varscan2
- TRIM58 | c.1367T>G p.L456R | Missense Mutation (SNP) | VAF 63/226 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.988); called by muse, mutect2, varscan2
- TTC7A | c.2434T>A p.C812S | Missense Mutation (SNP) | VAF 26/78 reads (33%) | SIFT tolerated (1); PolyPhen benign (0); called by muse, mutect2, varscan2
- TTN | c.39347T>A p.L13116H (on ENST00000591111; = p.L5692H on NM_003319.4) | Missense Mutation (SNP) | VAF 37/90 reads (41%) | PolyPhen probably damaging (0.988); called by muse, mutect2, varscan2
- UBA2 | c.1450G>A p.D484N | Missense Mutation (SNP) | VAF 8/57 reads (14%) | SIFT deleterious (0.03); PolyPhen benign (0.133); called by muse, mutect2, varscan2
- ULK4 | c.1354_1355del p.K452Vfs*11 | Frame Shift Del (DEL) | VAF 13/41 reads (32%) | called by mutect2, pindel, varscan2
- USP7 | c.1173A>C p.K391N | Missense Mutation (SNP) | VAF 23/64 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- UTP25 | c.277G>A p.E93K | Missense Mutation (SNP) | VAF 48/168 reads (29%) | SIFT tolerated (0.11); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- VAX1 | c.96C>A p.S32R | Missense Mutation (SNP) | VAF 77/164 reads (47%) | SIFT tolerated, low confidence (0.08); PolyPhen benign (0.021); called by muse, mutect2, varscan2
- WNT11 | c.410G>C p.G137A | Missense Mutation (SNP) | VAF 6/11 reads (55%) | SIFT tolerated (0.66); PolyPhen benign (0.022); called by muse, mutect2, varscan2
- XPO5 | c.2897C>A p.T966N | Missense Mutation (SNP) | VAF 43/164 reads (26%) | SIFT deleterious (0); PolyPhen possibly damaging (0.674); called by muse, mutect2, varscan2
- ZFHX3 | c.9991T>C p.Y3331H | Missense Mutation (SNP) | VAF 31/103 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); called by muse, mutect2, varscan2
- ZFHX4 | c.6445G>C p.D2149H | Missense Mutation (SNP) | VAF 28/115 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.971); called by muse, mutect2, varscan2
- ZFP36 | c.13T>A p.Y5N | Missense Mutation (SNP) | VAF 237/404 reads (59%) | SIFT tolerated, low confidence (0.15); PolyPhen benign (0); called by muse, mutect2, varscan2
- ZNF407 | c.4274G>T p.G1425V | Missense Mutation (SNP) | VAF 56/271 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.976); called by muse, mutect2, varscan2
- ZNF507 | c.461T>A p.I154K | Missense Mutation (SNP) | VAF 84/330 reads (25%) | SIFT deleterious (0); PolyPhen possibly damaging (0.726); called by muse, mutect2, varscan2
- ZNF507 | c.1576C>T p.P526S | Missense Mutation (SNP) | VAF 70/292 reads (24%) | SIFT tolerated (0.25); PolyPhen benign (0.031); called by muse, mutect2, varscan2
- ZNF639 | c.201C>A p.D67E | Missense Mutation (SNP) | VAF 108/366 reads (30%) | SIFT tolerated, low confidence (0.71); PolyPhen benign (0); called by muse, mutect2, varscan2
- ZNF804B | c.321dup p.Q108Tfs*6 | Frame Shift Ins (INS) | VAF 54/225 reads (24%) | called by mutect2, pindel, varscan2
- ZSCAN21 | c.1043T>G p.L348R | Missense Mutation (SNP) | VAF 176/581 reads (30%) | SIFT deleterious (0); PolyPhen possibly damaging (0.518); called by muse, mutect2, varscan2
- ADAM19 | c.1186C>T p.L396= | Silent (SNP) | VAF 51/182 reads (28%) | called by muse, mutect2, varscan2
- ADGRE3 | c.171A>C p.L57= | Silent (SNP) | VAF 38/163 reads (23%) | catalogued as rs1245561922; called by muse, mutect2, varscan2
- ADGRV1 | c.5634A>G p.P1878= | Silent (SNP) | VAF 24/109 reads (22%) | called by muse, mutect2, varscan2
- ARHGAP6 | c.94C>T p.L32= | Silent (SNP) | VAF 16/46 reads (35%) | called by muse, mutect2, varscan2
- ATP6V1D | c.360A>G p.E120= | Silent (SNP) | VAF 20/36 reads (56%) | called by muse, mutect2, varscan2
- CADPS2 | c.1842T>C p.D614= | Silent (SNP) | VAF 24/122 reads (20%) | called by muse, mutect2, varscan2
- CCDC17 | c.1230T>G p.A410= | Silent (SNP) | VAF 62/182 reads (34%) | called by muse, mutect2, varscan2
- CCDC88C | c.3324C>T p.N1108= | Silent (SNP) | VAF 34/81 reads (42%) | called by muse, mutect2, varscan2
- CEBPA | c.645G>A p.Q215= | Silent (SNP) | VAF 4/18 reads (22%) | called by mutect2, varscan2
- CNST | c.1737C>G p.L579= | Silent (SNP) | VAF 38/143 reads (27%) | catalogued as COSV63622356; called by muse, mutect2, varscan2
- CSMD3 | c.2199T>C p.L733= (on ENST00000297405 / NM_001363185.1; = p.L629= on NM_052900.3) | Silent (SNP) | VAF 23/87 reads (26%) | called by muse, mutect2, varscan2
- ERMP1 | c.1743T>A p.I581= | Silent (SNP) | VAF 46/144 reads (32%) | called by muse, mutect2, varscan2
- FAM83B | c.2952T>G p.G984= | Silent (SNP) | VAF 86/305 reads (28%) | called by muse, varscan2
- GTPBP10 | c.1140T>A p.T380= | Silent (SNP) | VAF 62/224 reads (28%) | catalogued as rs771785955; called by muse, mutect2, varscan2
- GZF1 | c.2016A>G p.A672= | Silent (SNP) | VAF 68/136 reads (50%) | called by muse, mutect2, varscan2
- IL16 | c.3693A>C p.T1231= (on ENST00000302987 / NM_172217.5; = p.T530= on NM_004513.6 and 1 other RefSeq transcript) | Silent (SNP) | VAF 11/57 reads (19%) | called by muse, mutect2, varscan2
- KIAA1671 | c.5310C>T p.R1770= | Silent (SNP) | VAF 19/46 reads (41%) | catalogued as rs779266035, COSV100625640; called by muse, mutect2, varscan2
- MAST1 | c.1866C>T p.S622= | Silent (SNP) | VAF 40/144 reads (28%) | called by muse, mutect2, varscan2
- MED23 | c.3702A>T p.V1234= | Silent (SNP) | VAF 24/62 reads (39%) | catalogued as COSV63433387; called by muse, mutect2, varscan2
- NOTCH3 | c.3553C>T p.L1185= | Silent (SNP) | VAF 33/106 reads (31%) | called by muse, mutect2, varscan2
- OBSCN | c.13155C>T p.N4385= | Silent (SNP) | VAF 55/144 reads (38%) | catalogued as rs568898759, COSV99484772; called by muse, mutect2, varscan2
- PCDH15 | c.276A>G p.Q92= | Silent (SNP) | VAF 26/72 reads (36%) | called by muse, mutect2, varscan2
- PRTG | c.795C>T p.I265= | Silent (SNP) | VAF 88/358 reads (25%) | called by muse, mutect2, varscan2
- PTBP1 | c.738C>T p.I246= | Silent (SNP) | VAF 78/283 reads (28%) | catalogued as rs747460224; called by muse, mutect2, varscan2
- RAP1GAP | c.453T>G p.P151= | Silent (SNP) | VAF 48/107 reads (45%) | called by muse, mutect2, varscan2
- RBMXL3 | c.2058T>A p.P686= | Silent (SNP) | VAF 89/205 reads (43%) | called by muse, mutect2, varscan2
- RFX7 | c.1218A>G p.E406= (on ENST00000559447 / NM_001368074.1; = p.E503= on NM_022841.7 and 1 other RefSeq transcript) | Silent (SNP) | VAF 60/227 reads (26%) | called by muse, mutect2, varscan2
- RGS7BP | c.444T>C p.S148= | Silent (SNP) | VAF 12/60 reads (20%) | called by muse, mutect2, varscan2
- RTL1 | c.825C>T p.S275= | Silent (SNP) | VAF 20/58 reads (34%) | catalogued as rs1158841422; called by muse, mutect2
- SCN10A | c.1401A>T p.S467= | Silent (SNP) | VAF 15/50 reads (30%) | called by muse, mutect2, varscan2
- SFXN5 | c.42T>C p.S14= | Silent (SNP) | VAF 93/219 reads (42%) | called by muse, mutect2, varscan2
- SRRM2 | c.5301T>C p.P1767= | Silent (SNP) | VAF 137/430 reads (32%) | called by muse, mutect2, varscan2
- STAT1 | c.1413C>T p.I471= | Silent (SNP) | VAF 19/132 reads (14%) | catalogued as COSV100738541; called by muse, mutect2, varscan2
- STRA8 | c.435T>A p.G145= (on ENST00000275764; = p.G123= on NM_182489.2) | Silent (SNP) | VAF 86/348 reads (25%) | called by muse, mutect2, varscan2
- TBC1D8B | c.1956A>T p.T652= | Silent (SNP) | VAF 114/287 reads (40%) | called by muse, mutect2, varscan2
- TCL1B | c.255C>T p.P85= | Silent (SNP) | VAF 80/190 reads (42%) | catalogued as rs760650681, COSV100525751, COSV61552418; called by muse, mutect2, varscan2
- TIMM17A | c.471T>C p.T157= | Silent (SNP) | VAF 72/258 reads (28%) | called by muse, mutect2, varscan2
- TLE2 | c.738G>A p.E246= | Silent (SNP) | VAF 33/101 reads (33%) | called by muse, mutect2, varscan2
- TMEM185B | c.675C>A p.L225= | Silent (SNP) | VAF 9/255 reads (4%) | called by muse, mutect2
- TRAPPC12 | c.879C>T p.P293= | Silent (SNP) | VAF 54/182 reads (30%) | catalogued as rs777042481; called by muse, mutect2
- TRPM5 | c.78C>T p.G26= | Silent (SNP) | VAF 40/105 reads (38%) | catalogued as rs759599505, COSV99329902; called by muse, mutect2, varscan2
- TXNIP | c.381T>C p.A127= | Silent (SNP) | VAF 74/290 reads (26%) | called by muse, mutect2, varscan2
- USP30 | c.567G>A p.V189= | Silent (SNP) | VAF 6/78 reads (8%) | called by muse, mutect2
- ZDHHC21 | c.498T>G p.R166= | Silent (SNP) | VAF 20/66 reads (30%) | catalogued as COSV101099674; called by muse, mutect2, varscan2
- ZNF844 | c.159A>G p.E53= | Silent (SNP) | VAF 9/36 reads (25%) | called by muse, mutect2, varscan2
- AAGAB | c.535+5061T>C | Intron (SNP) | VAF 8/34 reads (24%) | called by muse, mutect2, varscan2
- ACOT8 | c.646+77A>G | Intron (SNP) | VAF 16/43 reads (37%) | called by muse, mutect2, varscan2
- ADAM22 | chr7:88199256 A>T | 3'Flank (SNP) | VAF 15/74 reads (20%) | called by muse, mutect2, varscan2
- ADCY6 | c.-660T>A | 5'UTR (SNP) | VAF 7/9 reads (78%) | called by muse, mutect2, varscan2
- ADCY7 | c.1935+39T>G | Intron (SNP) | VAF 11/37 reads (30%) | called by muse, mutect2, varscan2
- AEN | c.*886T>A | 3'UTR (SNP) | VAF 104/379 reads (27%) | called by muse, mutect2, varscan2
- AKT2 | c.-84-9751G>A | Intron (SNP) | VAF 54/213 reads (25%) | catalogued as rs913191607; called by muse, mutect2, varscan2
- ANKRD6 | c.1486-27T>A | Intron (SNP) | VAF 9/21 reads (43%) | called by muse, varscan2
- AQP4 | c.*1C>G | 3'UTR (SNP) | VAF 50/187 reads (27%) | called by muse, mutect2, varscan2
- ARHGEF18 | c.*366G>C | 3'UTR (SNP) | VAF 51/161 reads (32%) | called by muse, mutect2, varscan2
- ARR3 | c.39+30G>A | Intron (SNP) | VAF 41/96 reads (43%) | catalogued as rs1257927805; called by muse, mutect2, varscan2
- ASAH1 | c.*882T>G | 3'UTR (SNP) | VAF 16/41 reads (39%) | called by muse, mutect2, varscan2
- BEND6 | chr6:56954566 C>A | 5'Flank (SNP) | VAF 40/134 reads (30%) | called by muse, mutect2, varscan2
- BMP6 | c.*764C>T | 3'UTR (SNP) | VAF 31/107 reads (29%) | called by muse, mutect2
- BMP6 | c.*900T>C | 3'UTR (SNP) | VAF 30/100 reads (30%) | called by muse, mutect2
- BMP6 | c.*902A>G | 3'UTR (SNP) | VAF 30/98 reads (31%) | catalogued as rs560288018; called by muse, mutect2
- BRAF | chr7:140734330 A>G | 3'Flank (SNP) | VAF 8/22 reads (36%) | called by muse, varscan2
- BRPF3 | c.*2142T>G | 3'UTR (SNP) | VAF 7/24 reads (29%) | called by muse, mutect2, varscan2
- BTBD7 | c.1162+5446_1162+5449del | Intron (DEL) | VAF 26/72 reads (36%) | catalogued as rs1318266008; called by mutect2, pindel, varscan2
- C15orf61 | c.346+556C>A | Intron (SNP) | VAF 69/314 reads (22%) | called by muse, mutect2, varscan2
- C1orf210 | chr1:43281946 C>A | 3'Flank (SNP) | VAF 17/68 reads (25%) | called by muse, mutect2, varscan2
- C1orf210 | chr1:43281947 C>A | 3'Flank (SNP) | VAF 17/67 reads (25%) | called by muse, varscan2
- C21orf91 | c.*509T>C | 3'UTR (SNP) | VAF 19/51 reads (37%) | called by muse, mutect2
- CACNA2D1 | chr7:81946653 T>A | 3'Flank (SNP) | VAF 37/161 reads (23%) | called by muse, mutect2, varscan2
- CACYBP | c.*1313T>C | 3'UTR (SNP) | VAF 15/87 reads (17%) | called by muse, mutect2, varscan2
- CAPZA2 | c.*473T>C | 3'UTR (SNP) | VAF 19/66 reads (29%) | called by muse, mutect2, varscan2
- CARMIL1 | c.615-114T>A | Intron (SNP) | VAF 15/53 reads (28%) | called by muse, mutect2
- CATSPERG | c.-15+410G>C | Intron (SNP) | VAF 22/110 reads (20%) | called by muse, mutect2, varscan2
- CCAR2 | c.1845+49C>T | Intron (SNP) | VAF 17/41 reads (41%) | called by muse, mutect2, varscan2
- CCDC127 | c.*285T>C | 3'UTR (SNP) | VAF 25/88 reads (28%) | called by muse, mutect2, varscan2
- CCDC186 | c.*3879T>A | 3'UTR (SNP) | VAF 22/48 reads (46%) | catalogued as rs917283565; called by muse, mutect2, varscan2
- CCL24 | c.*12C>T | 3'UTR (SNP) | VAF 28/111 reads (25%) | called by muse, mutect2, varscan2
- CCSAP | c.*1347T>C | 3'UTR (SNP) | VAF 28/155 reads (18%) | called by muse, mutect2, varscan2
- CDCP1 | c.*2736G>A | 3'UTR (SNP) | VAF 12/61 reads (20%) | catalogued as rs1357271136; called by muse, mutect2, varscan2
- CELA2A | c.*65A>G | 3'UTR (SNP) | VAF 134/398 reads (34%) | called by muse, mutect2, varscan2
- CES4A | c.1162-28C>T | Intron (SNP) | VAF 10/34 reads (29%) | catalogued as rs919618366; called by muse, mutect2
- CFAP61 | c.2060+111C>A | Intron (SNP) | VAF 82/322 reads (25%) | called by muse, mutect2, varscan2
- CFLAR | c.*168T>C | 3'UTR (SNP) | VAF 42/99 reads (42%) | called by muse, mutect2, varscan2
- CGN | c.*159A>T | 3'UTR (SNP) | VAF 22/69 reads (32%) | called by muse, mutect2, varscan2
- CHGB | c.*89C>A | 3'UTR (SNP) | VAF 92/228 reads (40%) | called by muse, mutect2, varscan2
- CHIC2 | c.*246T>A | 3'UTR (SNP) | VAF 35/95 reads (37%) | called by muse, mutect2, varscan2
- CLNK | c.*2923A>T | 3'UTR (SNP) | VAF 16/37 reads (43%) | called by muse, mutect2, varscan2
- CMKLR1 | c.*3386G>A | 3'UTR (SNP) | VAF 60/170 reads (35%) | called by muse, mutect2, varscan2
- CNOT1 | c.*725T>C | 3'UTR (SNP) | VAF 14/40 reads (35%) | called by muse, mutect2, varscan2
- COL1A2 | c.2295+90G>A | Intron (SNP) | VAF 6/22 reads (27%) | called by muse, mutect2, varscan2
- CORO1C | c.-5-1752_-5-1742del | Intron (DEL) | VAF 56/182 reads (31%) | called by mutect2, pindel, varscan2
- CPNE5 | c.*376C>G | 3'UTR (SNP) | VAF 26/95 reads (27%) | called by muse, mutect2, varscan2
- CRB1 | c.*496_*499del | 3'UTR (DEL) | VAF 13/30 reads (43%) | called by pindel, varscan2
- CSRNP3 | c.*996G>A | 3'UTR (SNP) | VAF 8/33 reads (24%) | catalogued as rs1055685353; called by muse, mutect2, varscan2
- CTSB | c.*488T>G | 3'UTR (SNP) | VAF 22/87 reads (25%) | called by muse, mutect2, varscan2
- DDN | c.*650del | 3'UTR (DEL) | VAF 22/83 reads (27%) | called by mutect2, pindel, varscan2
- DENND3 | c.*81C>T | 3'UTR (SNP) | VAF 17/44 reads (39%) | called by muse, mutect2, varscan2
- DENND4C | chr9:19373144 T>A | 3'Flank (SNP) | VAF 4/21 reads (19%) | called by muse, mutect2, varscan2
- DHDDS | c.*1152T>G | 3'UTR (SNP) | VAF 36/83 reads (43%) | called by muse, mutect2, varscan2
- DMD | c.*288del | 3'UTR (DEL) | VAF 8/58 reads (14%) | called by mutect2, pindel, varscan2
- DNAAF3 | c.86-79A>T | Intron (SNP) | VAF 29/95 reads (31%) | called by muse, mutect2, varscan2
- DNAJC19 | c.*286G>C | 3'UTR (SNP) | VAF 15/85 reads (18%) | called by muse, mutect2, varscan2
- DNAJC2 | c.-60T>A | 5'UTR (SNP) | VAF 24/66 reads (36%) | called by muse, mutect2, varscan2
- DPH1 | c.1008-50T>C | Intron (SNP) | VAF 7/22 reads (32%) | catalogued as rs372258424; called by muse, mutect2, varscan2
- EDRF1 | c.3394-60T>C | Intron (SNP) | VAF 17/42 reads (40%) | called by muse, mutect2, varscan2
- EFNB1 | c.-565G>A | 5'UTR (SNP) | VAF 115/219 reads (53%) | catalogued as rs1405479950; called by muse, mutect2, varscan2
- ELFN2 | c.*2619G>A | 3'UTR (SNP) | VAF 69/177 reads (39%) | called by muse, mutect2, varscan2
- ENDOV | c.*1899T>A | 3'UTR (SNP) | VAF 31/86 reads (36%) | called by muse, mutect2, varscan2
- EP300 | c.*327T>C | 3'UTR (SNP) | VAF 10/30 reads (33%) | called by muse, mutect2, varscan2
- EPB41L4A | c.*1713A>C | 3'UTR (SNP) | VAF 14/60 reads (23%) | called by muse, mutect2, varscan2
- EPS15 | c.*1213A>C | 3'UTR (SNP) | VAF 23/65 reads (35%) | called by muse, mutect2, varscan2
- FAM111A | c.-12C>G | 5'UTR (SNP) | VAF 16/526 reads (3%) | called by muse, mutect2
- FAM162A | c.*1210A>C | 3'UTR (SNP) | VAF 21/87 reads (24%) | called by muse, mutect2, varscan2
- FAM186B | c.97-39T>C | Intron (SNP) | VAF 17/48 reads (35%) | called by muse, mutect2, varscan2
- FGFR1OP2 | c.*781T>G | 3'UTR (SNP) | VAF 23/48 reads (48%) | called by muse, mutect2, varscan2
- FMNL1 | c.328-59T>G | Intron (SNP) | VAF 21/36 reads (58%) | called by muse, mutect2, varscan2
- FNBP1 | c.*1961C>T | 3'UTR (SNP) | VAF 51/201 reads (25%) | called by muse, mutect2, varscan2
- FOXN3 | c.*438T>G | 3'UTR (SNP) | VAF 43/106 reads (41%) | called by muse, mutect2, varscan2
- GAS1 | c.-107C>G | 5'UTR (SNP) | VAF 39/131 reads (30%) | catalogued as rs1158156713; called by muse, mutect2, varscan2
- GATAD2B | c.*39T>C | 3'UTR (SNP) | VAF 178/360 reads (49%) | called by muse, mutect2, varscan2
- GGCT | c.*273G>A | 3'UTR (SNP) | VAF 27/106 reads (25%) | called by muse, mutect2, varscan2
- GIGYF2 | c.*771T>C | 3'UTR (SNP) | VAF 15/35 reads (43%) | called by muse, mutect2, varscan2
- GIT2 | c.-66G>A | 5'UTR (SNP) | VAF 20/63 reads (32%) | called by muse, mutect2, varscan2
- GMNC | c.*1776A>T | 3'UTR (SNP) | VAF 33/111 reads (30%) | called by muse, mutect2, varscan2
- GORASP2 | c.*258T>C | 3'UTR (SNP) | VAF 3/12 reads (25%) | called by muse, mutect2
- GPR35 | c.-149+271A>T | Intron (SNP) | VAF 8/17 reads (47%) | called by muse, mutect2, varscan2
- GRK2 | c.*1031T>G | 3'UTR (SNP) | VAF 58/160 reads (36%) | called by muse, mutect2, varscan2
- GSN | c.*125T>C | 3'UTR (SNP) | VAF 6/22 reads (27%) | called by muse, varscan2
- H4C11 | c.-4C>T | 5'UTR (SNP) | VAF 49/198 reads (25%) | catalogued as rs773234876; called by muse, mutect2, varscan2
- HERPUD1 | c.*562T>C | 3'UTR (SNP) | VAF 13/43 reads (30%) | called by muse, mutect2, varscan2
- HIF1AN | c.*1248T>G | 3'UTR (SNP) | VAF 50/123 reads (41%) | called by muse, mutect2, varscan2
- HNRNPU | c.988-25T>C | Intron (SNP) | VAF 22/101 reads (22%) | called by muse, mutect2, varscan2
- HYDIN2 | n.1085C>G | RNA (SNP) | VAF 12/23 reads (52%) | called by mutect2, varscan2
- IFT27 | c.353-51T>G | Intron (SNP) | VAF 71/153 reads (46%) | called by muse, mutect2, varscan2
- IL6ST | c.*2170T>C | 3'UTR (SNP) | VAF 8/28 reads (29%) | called by muse, mutect2, varscan2
- IL6ST | c.*1956C>A | 3'UTR (SNP) | VAF 28/118 reads (24%) | called by muse, mutect2, varscan2
- INSIG2 | c.*1502C>G | 3'UTR (SNP) | VAF 25/66 reads (38%) | called by muse, mutect2, varscan2
- IQGAP2 | c.*737T>A | 3'UTR (SNP) | VAF 18/90 reads (20%) | called by muse, mutect2, varscan2
- IREB2 | c.*1047T>C | 3'UTR (SNP) | VAF 20/67 reads (30%) | called by muse, mutect2, varscan2
- ITPR1 | c.5145+99C>G | Intron (SNP) | VAF 20/54 reads (37%) | called by muse, mutect2, varscan2
- KANK1 | c.3245+51T>G | Intron (SNP) | VAF 146/499 reads (29%) | called by muse, mutect2, varscan2
- KCNJ3 | c.*3029T>C | 3'UTR (SNP) | VAF 13/31 reads (42%) | called by muse, mutect2
- KCNMA1 | c.3017-161C>T | Intron (SNP) | VAF 14/35 reads (40%) | called by muse, mutect2, varscan2
- KIRREL3 | chr11:127003590 G>T | 5'Flank (SNP) | VAF 62/171 reads (36%) | called by muse, mutect2, varscan2
- KLF6 | c.*900T>C | 3'UTR (SNP) | VAF 39/104 reads (38%) | called by muse, mutect2, varscan2
- KMT2E | c.2197-18T>A | Intron (SNP) | VAF 19/58 reads (33%) | called by muse, mutect2, varscan2
- KRAS | c.112-6447T>A | Intron (SNP) | VAF 10/28 reads (36%) | called by muse, mutect2, varscan2
- KRTCAP3 | c.*10T>A | 3'UTR (SNP) | VAF 23/66 reads (35%) | called by muse, mutect2, varscan2
- LCA5 | c.*1446G>A | 3'UTR (SNP) | VAF 58/110 reads (53%) | catalogued as rs1390565160; called by muse, mutect2, varscan2
- LCA5 | c.*43A>G | 3'UTR (SNP) | VAF 10/44 reads (23%) | called by muse, mutect2
- LEMD3 | c.*1500T>A | 3'UTR (SNP) | VAF 30/59 reads (51%) | called by muse, mutect2, varscan2
- LMAN1 | c.*767T>C | 3'UTR (SNP) | VAF 35/116 reads (30%) | called by muse, mutect2, varscan2
- LMBRD2 | c.*3010C>A | 3'UTR (SNP) | VAF 32/123 reads (26%) | called by muse, mutect2, varscan2
- LTBP4 | c.*49T>A | 3'UTR (SNP) | VAF 8/34 reads (24%) | called by muse, varscan2
- LUC7L3 | chr17:50754988 T>G | 3'Flank (SNP) | VAF 17/51 reads (33%) | called by muse, mutect2, varscan2
- LYNX1 | c.*900G>A | 3'UTR (SNP) | VAF 17/76 reads (22%) | catalogued as rs757698504; called by muse, mutect2, varscan2
- MAP4 | c.292+2647T>C | Intron (SNP) | VAF 21/90 reads (23%) | called by muse, mutect2, varscan2
- MAPK8IP1 | c.*624G>A | 3'UTR (SNP) | VAF 4/51 reads (8%) | called by muse, mutect2
- MARCHF5 | c.*2326T>G | 3'UTR (SNP) | VAF 33/85 reads (39%) | called by muse, mutect2, varscan2
- MDM1 | c.499-153T>G | Intron (SNP) | VAF 21/61 reads (34%) | called by muse, mutect2, varscan2
- MEF2C | c.*1702C>T | 3'UTR (SNP) | VAF 61/194 reads (31%) | called by muse, mutect2, varscan2
- MFSD14A | c.*513T>A | 3'UTR (SNP) | VAF 20/46 reads (43%) | catalogued as rs555577797; called by mutect2, varscan2
- MICALL1 | c.*1840T>G | 3'UTR (SNP) | VAF 3/12 reads (25%) | called by muse, mutect2
- MPZL1 | c.*902A>C | 3'UTR (SNP) | VAF 39/72 reads (54%) | called by muse, mutect2, varscan2
- MRPS25 | c.*2041G>T | 3'UTR (SNP) | VAF 37/172 reads (22%) | called by muse, mutect2, varscan2
- MTDH | c.*4242T>A | 3'UTR (SNP) | VAF 18/34 reads (53%) | called by mutect2, varscan2
- MYBL1 | c.*2235T>A | 3'UTR (SNP) | VAF 28/76 reads (37%) | called by muse, mutect2, varscan2
- MYO1E | c.-1C>T | 5'UTR (SNP) | VAF 12/49 reads (24%) | catalogued as rs554973305; called by muse, mutect2, varscan2
- MYO1E | c.-2C>T | 5'UTR (SNP) | VAF 12/48 reads (25%) | catalogued as rs573448797, COSV55686570; called by muse, mutect2, varscan2
- NDRG1 | c.206-55T>A | Intron (SNP) | VAF 12/41 reads (29%) | called by muse, mutect2
- NDUFA4 | c.43-113A>C | Intron (SNP) | VAF 18/76 reads (24%) | called by muse, mutect2
- NDUFV3 | c.*406C>G | 3'UTR (SNP) | VAF 8/19 reads (42%) | called by muse, varscan2
- NEDD4L | c.1066-81T>A | Intron (SNP) | VAF 8/34 reads (24%) | called by muse, mutect2
- NEU3 | c.*208G>T | 3'UTR (SNP) | VAF 15/52 reads (29%) | called by muse, mutect2, varscan2
- NIPSNAP3A | c.*635T>A | 3'UTR (SNP) | VAF 10/56 reads (18%) | called by muse, mutect2, varscan2
- NKX3-2 | c.-93C>G | 5'UTR (SNP) | VAF 7/18 reads (39%) | called by muse, mutect2, varscan2
- NOL9 | c.*1490T>C | 3'UTR (SNP) | VAF 46/108 reads (43%) | called by muse, mutect2, varscan2
- NPTXR | c.*2457C>T | 3'UTR (SNP) | VAF 61/167 reads (37%) | called by muse, mutect2, varscan2
- NR2E1 | c.*1181A>C | 3'UTR (SNP) | VAF 14/37 reads (38%) | called by muse, mutect2, varscan2
- NR3C1 | c.*2625C>T | 3'UTR (SNP) | VAF 70/248 reads (28%) | catalogued as rs1303150840, COSV99196864; called by muse, mutect2, varscan2
- NSMAF | c.-91C>T | 5'UTR (SNP) | VAF 4/16 reads (25%) | called by muse, mutect2
- NUP93 | c.1086-113G>T | Intron (SNP) | VAF 6/13 reads (46%) | called by muse, mutect2, varscan2
- OLIG2 | c.*1016T>C | 3'UTR (SNP) | VAF 34/72 reads (47%) | called by muse, mutect2, varscan2
- ORAI2 | c.*4333A>G | 3'UTR (SNP) | VAF 31/122 reads (25%) | called by muse, mutect2, varscan2
- OSBPL10 | c.*3936G>A | 3'UTR (SNP) | VAF 27/86 reads (31%) | catalogued as rs763446960; called by muse, mutect2, varscan2
- P2RY1 | c.-640G>A | 5'UTR (SNP) | VAF 48/188 reads (26%) | catalogued as rs1034869040; called by muse, varscan2
- PAPOLB | c.*149G>C | 3'UTR (SNP) | VAF 24/86 reads (28%) | called by muse, mutect2, varscan2
- PCNX4 | c.*211T>A | 3'UTR (SNP) | VAF 15/51 reads (29%) | called by muse, mutect2, varscan2
- PEDS1-UBE2V1 | c.*352T>G | 3'UTR (SNP) | VAF 10/30 reads (33%) | called by muse, mutect2
- PHACTR2 | c.*1937T>C | 3'UTR (SNP) | VAF 9/30 reads (30%) | catalogued as rs577083716, COSV59853760; called by muse, varscan2
- PIN4 | c.118+11C>G | Intron (SNP) | VAF 33/61 reads (54%) | called by muse, mutect2, varscan2
- PLD6 | c.*510A>T | 3'UTR (SNP) | VAF 72/172 reads (42%) | called by muse, mutect2, varscan2
- PLEK2 | c.-54G>T | 5'UTR (SNP) | VAF 32/70 reads (46%) | called by muse, mutect2, varscan2
- PLSCR5 | c.-564T>A | 5'UTR (SNP) | VAF 8/31 reads (26%) | called by muse, mutect2, varscan2
- POU2F2 | c.303+297C>T | Intron (SNP) | VAF 15/73 reads (21%) | called by muse, mutect2, varscan2
- PPIL4 | c.*411T>A | 3'UTR (SNP) | VAF 34/83 reads (41%) | called by muse, mutect2, varscan2
- PPM1A | c.*5777A>T | 3'UTR (SNP) | VAF 29/69 reads (42%) | called by muse, mutect2, varscan2
- PPP1R3B | c.*361C>A | 3'UTR (SNP) | VAF 33/97 reads (34%) | catalogued as rs938438345; called by muse, mutect2, varscan2
- PRDM16 | c.*3884A>T | 3'UTR (SNP) | VAF 31/84 reads (37%) | called by muse, mutect2, varscan2
- PRPF4B | c.*772T>A | 3'UTR (SNP) | VAF 18/61 reads (30%) | called by muse, mutect2, varscan2
- PRR3 | c.170-291C>T | Intron (SNP) | VAF 23/74 reads (31%) | called by muse, mutect2, varscan2
- PRSS21 | c.92-28G>A | Intron (SNP) | VAF 40/109 reads (37%) | called by muse, mutect2, varscan2
- PRTG | c.*4921_*4957del | 3'UTR (DEL) | VAF 18/140 reads (13%) | called by mutect2, pindel
- PUM1 | c.1253-10T>C | Intron (SNP) | VAF 38/88 reads (43%) | called by muse, mutect2, varscan2
- QKI | c.*7213T>A | 3'UTR (SNP) | VAF 24/63 reads (38%) | called by muse, mutect2, varscan2
- RABL6 | c.706-443T>C | Intron (SNP) | VAF 14/56 reads (25%) | called by muse, mutect2, varscan2
- RAD21 | c.1471-517A>T | Intron (SNP) | VAF 13/44 reads (30%) | called by muse, mutect2, varscan2
- RAPGEF3 | c.1596+737C>T | Intron (SNP) | VAF 37/88 reads (42%) | called by muse, mutect2, varscan2
- RASIP1 | c.*148G>A | 3'UTR (SNP) | VAF 10/29 reads (34%) | called by muse, mutect2, varscan2
- RBM15B | c.*1625T>A | 3'UTR (SNP) | VAF 32/155 reads (21%) | called by muse, mutect2, varscan2
- RBM6 | c.-67+366T>A | Intron (SNP) | VAF 52/173 reads (30%) | called by muse, mutect2, varscan2
- RC3H2 | c.*3201C>A | 3'UTR (SNP) | VAF 29/122 reads (24%) | called by muse, mutect2, varscan2
- REXO2 | c.309+252T>C | Intron (SNP) | VAF 150/415 reads (36%) | called by muse, mutect2, varscan2
- RHD | c.*823A>G | 3'UTR (SNP) | VAF 15/21 reads (71%) | called by muse, mutect2, varscan2
- RHOA | c.*32T>C | 3'UTR (SNP) | VAF 244/816 reads (30%) | called by muse, mutect2, varscan2
- RHPN2 | c.*70T>A | 3'UTR (SNP) | VAF 24/82 reads (29%) | called by muse, mutect2, varscan2
- RIF1 | c.*2155T>G | 3'UTR (SNP) | VAF 54/123 reads (44%) | called by muse, mutect2, varscan2
- RIMS3 | chr1:40626052 del A | 3'Flank (DEL) | VAF 19/95 reads (20%) | called by mutect2, pindel, varscan2
- ROR2 | c.*35C>A | 3'UTR (SNP) | VAF 21/126 reads (17%) | called by muse, mutect2, varscan2
- RP2 | c.*843G>A | 3'UTR (SNP) | VAF 18/53 reads (34%) | called by muse, mutect2, varscan2
- RPL23 | c.*15+23A>G | Intron (SNP) | VAF 34/92 reads (37%) | called by mutect2, varscan2
- RPL37 | c.*5172T>C | 3'UTR (SNP) | VAF 41/135 reads (30%) | called by muse, mutect2, varscan2
- RPL7A | c.4-320G>C | Intron (SNP) | VAF 18/87 reads (21%) | called by muse, mutect2, varscan2
- RPLP0 | c.55-529T>C | Intron (SNP) | VAF 83/212 reads (39%) | called by muse, mutect2, varscan2
- RPS23 | c.5-10T>A | Intron (SNP) | VAF 39/172 reads (23%) | called by muse, mutect2, varscan2
- RPSA | c.793+9C>T | Intron (SNP) | VAF 33/97 reads (34%) | called by muse, mutect2, varscan2
- RRN3 | c.*1366T>C | 3'UTR (SNP) | VAF 11/28 reads (39%) | called by muse, mutect2, varscan2
- RRP1B | c.*1542T>A | 3'UTR (SNP) | VAF 46/99 reads (46%) | called by muse, mutect2, varscan2
- RTL8C | c.*272G>C | 3'UTR (SNP) | VAF 111/198 reads (56%) | called by muse, mutect2, varscan2
- SAMHD1 | c.1504-531T>G | Intron (SNP) | VAF 9/32 reads (28%) | called by muse, mutect2, varscan2
- SAR1B | c.*2262T>G | 3'UTR (SNP) | VAF 20/92 reads (22%) | called by muse, mutect2, varscan2
- SAXO1 | c.-192G>T | 5'UTR (SNP) | VAF 71/351 reads (20%) | called by muse, mutect2, varscan2
- SEC24A | c.*138C>G | 3'UTR (SNP) | VAF 19/60 reads (32%) | called by muse, mutect2, varscan2
- SECISBP2L | c.*1541T>A | 3'UTR (SNP) | VAF 19/98 reads (19%) | called by muse, mutect2, varscan2
- SEMA3A | c.*1492T>C | 3'UTR (SNP) | VAF 8/51 reads (16%) | catalogued as rs1391937015; called by muse, mutect2, varscan2
- SEMA3A | c.*1398T>C | 3'UTR (SNP) | VAF 19/87 reads (22%) | called by muse, mutect2, varscan2
- SEMA5A | c.*4791T>G | 3'UTR (SNP) | VAF 21/67 reads (31%) | called by muse, mutect2, varscan2
- SERP1 | c.*1897G>A | 3'UTR (SNP) | VAF 62/124 reads (50%) | called by muse, mutect2, varscan2
- SLC11A2 | chr12:50981260 A>T | 3'Flank (SNP) | VAF 18/57 reads (32%) | called by muse, mutect2, varscan2
- SLC12A1 | c.629-470C>G | Intron (SNP) | VAF 31/126 reads (25%) | catalogued as rs1020701548; called by muse, mutect2, varscan2
- SLC25A14 | c.*393T>A | 3'UTR (SNP) | VAF 4/14 reads (29%) | called by muse, mutect2
- SLC25A22 | c.*1251T>C | 3'UTR (SNP) | VAF 33/132 reads (25%) | called by muse, mutect2, varscan2
- SLC25A46 | c.*140T>G | 3'UTR (SNP) | VAF 43/121 reads (36%) | called by muse, mutect2, varscan2
- SLC30A1 | c.*1061A>C | 3'UTR (SNP) | VAF 18/104 reads (17%) | called by muse, mutect2, varscan2
- SLC30A9 | c.*369T>C | 3'UTR (SNP) | VAF 26/84 reads (31%) | called by muse, mutect2, varscan2
- SMAD2 | c.*2912T>G | 3'UTR (SNP) | VAF 19/98 reads (19%) | called by muse, mutect2, varscan2
- SMC5 | c.*1605T>A | 3'UTR (SNP) | VAF 20/70 reads (29%) | called by muse, mutect2, varscan2
- SMIM7 | c.*150+330C>A | Intron (SNP) | VAF 53/221 reads (24%) | called by muse, mutect2, varscan2
- SMNDC1 | chr10:110293246 A>T | 3'Flank (SNP) | VAF 23/78 reads (29%) | called by muse, mutect2, varscan2
- SNORA9 | chr7:44985570 C>A | 5'Flank (SNP) | VAF 53/178 reads (30%) | catalogued as rs535777741; called by muse, mutect2, varscan2
- SNX33 | c.*4870T>A | 3'UTR (SNP) | VAF 11/47 reads (23%) | called by muse, mutect2, varscan2
- SPAST | c.-256C>T | 5'UTR (SNP) | VAF 23/50 reads (46%) | called by muse, mutect2, varscan2
- SPATA31C2 | n.2406T>A | RNA (SNP) | VAF 8/24 reads (33%) | called by muse, mutect2, varscan2
- SPATA41 | chr15:100349969 C>A | 5'Flank (SNP) | VAF 101/322 reads (31%) | called by muse, mutect2, varscan2
- SPATA46 | c.103+40T>A | Intron (SNP) | VAF 20/75 reads (27%) | called by muse, mutect2, varscan2
- SRSF11 | c.338-630T>G | Intron (SNP) | VAF 20/47 reads (43%) | called by muse, mutect2, varscan2
- SSR1 | c.*5241C>T | 3'UTR (SNP) | VAF 18/87 reads (21%) | called by muse, mutect2, varscan2
- SSR1 | c.*128T>G | 3'UTR (SNP) | VAF 78/301 reads (26%) | called by muse, mutect2, varscan2
- SSX9P | n.221C>A | RNA (SNP) | VAF 93/244 reads (38%) | called by muse, mutect2, varscan2
- TAFA5 | c.*1636T>C | 3'UTR (SNP) | VAF 37/75 reads (49%) | called by muse, mutect2, varscan2
- TBC1D23 | c.*559T>C | 3'UTR (SNP) | VAF 19/88 reads (22%) | called by muse, mutect2, varscan2
- TC2N | c.*892T>A | 3'UTR (SNP) | VAF 13/42 reads (31%) | called by muse, mutect2, varscan2
- TDRKH | c.421+73T>A | Intron (SNP) | VAF 16/50 reads (32%) | catalogued as COSV64316726; called by muse, mutect2, varscan2
- TFEB | c.803+185T>G | Intron (SNP) | VAF 72/239 reads (30%) | called by muse, mutect2, varscan2
- THAP2 | c.71+749T>G | Intron (SNP) | VAF 16/44 reads (36%) | called by muse, mutect2, varscan2
- TIMM17A | c.*1044T>C | 3'UTR (SNP) | VAF 20/73 reads (27%) | called by muse, mutect2, varscan2
- TLR8 | c.3+3629A>G | Intron (SNP) | VAF 175/443 reads (40%) | called by muse, mutect2, varscan2
- TMEM123 | c.449-100T>C | Intron (SNP) | VAF 4/12 reads (33%) | called by muse, mutect2, varscan2
- TMEM132B | c.*7229T>A | 3'UTR (SNP) | VAF 19/51 reads (37%) | called by muse, mutect2, varscan2
- TMEM39A | c.*580A>T | 3'UTR (SNP) | VAF 17/93 reads (18%) | called by muse, mutect2, varscan2
- TMEM72 | c.*483G>A | 3'UTR (SNP) | VAF 43/109 reads (39%) | called by muse, mutect2, varscan2
- TNFRSF10D | c.*1873G>A | 3'UTR (SNP) | VAF 44/112 reads (39%) | catalogued as rs945460064; called by muse, mutect2, varscan2
- TNFRSF11A | c.*84C>A | 3'UTR (SNP) | VAF 39/172 reads (23%) | catalogued as rs1044522322; called by muse, mutect2, varscan2
- TNFSF13 | c.*326G>T | 3'UTR (SNP) | VAF 49/140 reads (35%) | called by muse, mutect2, varscan2
- TPGS1 | c.*33_*34insG | 3'UTR (INS) | VAF 6/24 reads (25%) | called by mutect2, pindel*, varscan2
- TPH1 | c.-414T>A | 5'UTR (SNP) | VAF 38/100 reads (38%) | called by muse, mutect2, varscan2
- TPP1 | c.1076-22T>C | Intron (SNP) | VAF 26/69 reads (38%) | catalogued as rs1253811702; called by muse, mutect2, varscan2
- TRAF3IP2 | chr6:111556443 C>G | 3'Flank (SNP) | VAF 13/42 reads (31%) | called by muse, mutect2, varscan2
- TRIM77BP | n.444G>A | RNA (SNP) | VAF 14/34 reads (41%) | called by muse, varscan2
- TTC3 | c.-1174T>A | 5'UTR (SNP) | VAF 35/74 reads (47%) | called by muse, mutect2, varscan2
- TXNDC5 | c.*826T>C | 3'UTR (SNP) | VAF 24/117 reads (21%) | called by muse, mutect2, varscan2
- U2SURP | c.*2980T>G | 3'UTR (SNP) | VAF 20/65 reads (31%) | called by muse, mutect2, varscan2
- UBA5 | c.*490T>A | 3'UTR (SNP) | VAF 20/87 reads (23%) | called by muse, mutect2, varscan2
- UBE2D3 | c.198+29T>C | Intron (SNP) | VAF 14/47 reads (30%) | called by muse, mutect2, varscan2
- UBXN7 | c.*5186T>C | 3'UTR (SNP) | VAF 67/105 reads (64%) | catalogued as rs1004655889, COSV56356292; called by muse, mutect2, varscan2
- USP34 | chr2:61184717 A>G | 3'Flank (SNP) | VAF 146/340 reads (43%) | called by muse, mutect2, varscan2
- UTP14A | chrX:129929794 T>C | 3'Flank (SNP) | VAF 11/47 reads (23%) | called by muse, mutect2, varscan2
- VAT1L | c.*5G>A | 3'UTR (SNP) | VAF 15/32 reads (47%) | called by muse, mutect2
- VEGFA | chr6:43786321 C>T | 3'Flank (SNP) | VAF 11/43 reads (26%) | catalogued as rs1293719095; called by muse, mutect2, varscan2
- VGLL3 | c.*4192A>G | 3'UTR (SNP) | VAF 56/109 reads (51%) | called by muse, mutect2, varscan2
- VIRMA | c.*332T>A | 3'UTR (SNP) | VAF 23/65 reads (35%) | called by muse, mutect2, varscan2
- VOPP1 | c.55-16501A>T | Intron (SNP) | VAF 32/122 reads (26%) | catalogued as rs547441540; called by muse, mutect2, varscan2
- VPS16 | chr20:2840721 C>G | 5'Flank (SNP) | VAF 8/20 reads (40%) | called by muse, varscan2
- WASL | c.*1247T>C | 3'UTR (SNP) | VAF 30/94 reads (32%) | called by muse, mutect2, varscan2
- WBP2NL | c.*1123T>A | 3'UTR (SNP) | VAF 7/19 reads (37%) | called by muse, mutect2, varscan2
- WWC1 | c.942-29C>T | Intron (SNP) | VAF 12/33 reads (36%) | called by muse, mutect2, varscan2
- WWTR1 | c.*2517T>A | 3'UTR (SNP) | VAF 16/56 reads (29%) | called by muse, mutect2, varscan2
- YIPF4 | c.*2476A>T | 3'UTR (SNP) | VAF 17/32 reads (53%) | called by muse, mutect2, varscan2
- ZBTB11 | chr3:101677160 G>A | 5'Flank (SNP) | VAF 58/252 reads (23%) | called by muse, mutect2, varscan2
- ZBTB24 | c.*2901T>G | 3'UTR (SNP) | VAF 39/119 reads (33%) | called by muse, mutect2, varscan2
- ZBTB38 | chr3:141449676 T>A | 3'Flank (SNP) | VAF 26/106 reads (25%) | called by muse, mutect2, varscan2
- ZFPM1 | c.*11T>C | 3'UTR (SNP) | VAF 17/106 reads (16%) | called by muse, mutect2, varscan2
- ZNF135 | c.*33A>G | 3'UTR (SNP) | VAF 115/418 reads (28%) | called by muse, mutect2, varscan2
- ZNF24 | c.*3085T>A | 3'UTR (SNP) | VAF 30/116 reads (26%) | called by muse, mutect2, varscan2
- ZNF354B | c.*548T>G | 3'UTR (SNP) | VAF 6/22 reads (27%) | called by muse, mutect2, varscan2
- ZNF354C | c.*1174G>T | 3'UTR (SNP) | VAF 17/46 reads (37%) | called by muse, mutect2, varscan2
- ZNF37A | c.*2079G>A | 3'UTR (SNP) | VAF 25/64 reads (39%) | called by muse, mutect2, varscan2
- ZNF516 | chr18:76497385 C>A | 5'Flank (SNP) | VAF 21/79 reads (27%) | called by muse, mutect2, varscan2
- ZXDA | c.*201C>T | 3'UTR (SNP) | VAF 41/98 reads (42%) | called by muse, mutect2, varscan2
